Somatic mutation profile of tumor specimen CDDP-ABLQ-TTP2-B (aliquot CDDP-ABLQ-TTP2-B-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABLQ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74 years.
Specimen CDDP-ABLQ-TTP2-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63906f01-5ae2-4b29-b311-ca87207a5647.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABLQ-NB1-A (Blood Derived Normal), aliquot CDDP-ABLQ-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81020e73-6c7c-45d4-8638-910c997342ff

The open-access MAF lists 346 somatic variants for this specimen: 234 protein-altering or splice-affecting, 61 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 61, Intron 28, Nonsense Mutation 18, Frame Shift Del 10, 5'UTR 9, RNA 7, 3'Flank 3, Splice Region 3, Splice Site 2, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.985G>A p.G329S (on ENST00000545399 / NM_001256214.2; = p.G316S on NM_152296.5) | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs869320661, CM163568; ClinVar: pathogenic; called by muse, mutect2
- GHR | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 56/243 reads (23%) | catalogued as rs121909371, CM050055, COSV100052208, COSV50132600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 134/254 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 136/255 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 70/184 reads (38%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.823G>T p.G275W (on ENST00000614293; = p.G245W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV55807071; called by muse, mutect2, varscan2
- AC008676.3 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV56638200; called by muse, mutect2, varscan2
- ACTC1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51761742; called by muse, mutect2, varscan2
- ADARB2 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV67238279; called by muse, mutect2, varscan2
- ADGRD1 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs150620459; called by muse, mutect2, varscan2
- AFAP1L2 | c.1285G>C p.A429P | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58418873; called by muse, mutect2, varscan2
- AGRN | c.787G>C p.A263P | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.78); catalogued as COSV65072491; called by muse, mutect2, varscan2
- AMELX | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.025); catalogued as COSV61633441; called by muse, mutect2, varscan2
- ANKIB1 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV56066437; called by muse, mutect2, varscan2
- ANKRD24 | c.1684A>T p.I562L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV53676020; called by muse, mutect2, varscan2
- ANKRD7 | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54554414, COSV54556600; called by muse, mutect2, varscan2
- APOD | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279679431, COSV58402814; called by muse, mutect2, varscan2
- AR | c.1215G>C p.Q405H | Missense Mutation (SNP) | VAF 143/474 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65964386; called by muse, mutect2, varscan2
- ARHGEF33 | c.2062A>G p.S688G | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67258331; called by muse, mutect2, varscan2
- ARMH4 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 119/216 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs142845597; called by muse, mutect2, varscan2
- ATAD2B | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV53205990; called by muse, mutect2, varscan2
- ATG10 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56433175; called by muse, mutect2, varscan2
- ATP2A2 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 168/320 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM094337, COSV58047810; called by muse, mutect2, varscan2
- ATRX | c.6829G>C p.E2277Q | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64871445, COSV64875814, COSV64883974; called by muse, mutect2, varscan2
- BEST3 | c.1781G>C p.G594A | Missense Mutation (SNP) | VAF 162/295 reads (55%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.017); catalogued as COSV58304093, COSV58305929; called by muse, mutect2, varscan2
- BEX4 | c.298A>T p.R100W | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65516245; called by muse, mutect2, varscan2
- BICRAL | c.980A>T p.N327I | Missense Mutation (SNP) | VAF 172/422 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV58408634; called by muse, mutect2, varscan2
- BLNK | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 105/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1006565682, COSV56415233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC2 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 136/351 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as rs535983413, COSV66156428; called by muse, mutect2, varscan2
- C1QTNF4 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV56783444; called by muse, mutect2, varscan2
- C8orf33 | c.154A>C p.N52H | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.693); catalogued as rs551244312; called by muse, mutect2
- CAPSL | c.264T>A p.D88E | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV68439507; called by muse, mutect2, varscan2
- CBY2 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV60119978; called by muse, mutect2, varscan2
- CD40LG | c.511A>T p.I171F | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as CD034001, CD034353, CD961882, COSV65699089; called by muse, mutect2, varscan2
- CELA3B | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100448870, COSV61404101; called by muse, mutect2, varscan2
- CELSR1 | c.1635C>G p.I545M | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.562); catalogued as COSV53100560; called by muse, mutect2, varscan2
- CEP350 | c.3446C>T p.S1149F | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.467); catalogued as COSV62610057; called by muse, mutect2, varscan2
- COL6A1 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 118/391 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs780234826, CM141367, COSV62611731; called by muse, mutect2, varscan2
- CTTN | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs547452914, COSV57230451, COSV57236455; called by muse, mutect2, varscan2
- CUL4B | c.2288G>A p.S763N | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV60691375; called by muse, mutect2, varscan2
- CUL4B | c.1924A>T p.T642S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60691384; called by muse, mutect2, varscan2
- CYFIP2 | c.2108T>A p.L703Q (on ENST00000616178 / NM_001291722.2; = p.L678Q on NM_014376.4) | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59041818, COSV59051872; called by muse, mutect2, varscan2
- CYP8B1 | c.799del p.V267Yfs*12 | Frame Shift Del (DEL) | VAF 38/101 reads (38%) | catalogued as rs1559374417; called by mutect2, pindel, varscan2
- DAAM1 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs776038942; called by muse, mutect2, varscan2
- DACT1 | c.2471G>T p.R824L | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770244112, COSV60019206, COSV60023634; called by muse, mutect2, varscan2
- DENND5B | c.2897G>A p.G966E | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV60908731; called by muse, varscan2
- DPYSL4 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759346668, COSV53846253; called by muse, mutect2
- ECEL1 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as COSV58812582, COSV58814387, COSV58814488; called by muse, mutect2, varscan2
- EHBP1 | c.2529C>A p.N843K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV50439787; called by muse, mutect2, varscan2
- FOXC1 | c.1019C>G p.S340W | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66516754; called by muse, mutect2
- FZD9 | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 44/174 reads (25%) | catalogued as COSV60671455; called by muse, mutect2, varscan2
- G0S2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 59/142 reads (42%) | catalogued as COSV100884471, COSV65433305; called by muse, mutect2, varscan2
- GRINA | c.693+1G>T p.X231_splice | Splice Site (SNP) | VAF 11/145 reads (8%) | catalogued as rs112590665; called by muse, mutect2
- HCN4 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56087666; called by muse, mutect2, varscan2
- HYAL4 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs376271207; called by muse, mutect2, varscan2
- IGHG1 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1342808728; called by muse, mutect2, varscan2
- IL11RA | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 222/524 reads (42%) | catalogued as COSV52405791; called by muse, mutect2, varscan2
- ITFG1 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 136/403 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV54534882; called by muse, mutect2, varscan2
- ITIH6 | c.1976C>A p.P659H | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54494900; called by muse, mutect2, varscan2
- ITPR1 | c.6846C>A p.N2282K (on ENST00000354582; = p.N2227K on NM_002222.7) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57005260; called by muse, mutect2, varscan2
- ITPR2 | c.6660C>G p.F2220L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV67270791; called by muse, mutect2, varscan2
- IZUMO3 | c.562C>G p.L188V (on ENST00000543880 / NM_001365008.2; = p.L182V on NM_001271706.1) | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.578); catalogued as COSV69048759; called by muse, mutect2, varscan2
- JPH3 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1264044529, COSV52463898; called by muse, varscan2
- JUND | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 49/170 reads (29%) | catalogued as COSV53254930; called by muse, mutect2, varscan2
- KHDC4 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV64165845, COSV64165862; called by muse, mutect2, varscan2
- KIF4B | c.1095G>T p.L365F | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101469461, COSV70531717; called by muse, mutect2, varscan2
- KLF8 | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV63848947; called by muse, mutect2, varscan2
- KRTAP10-6 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 278/694 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59981024; called by muse, mutect2, varscan2
- KRTAP10-6 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 274/687 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs1555926650, COSV59981030; called by muse, mutect2, varscan2
- KTI12 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs372433236, COSV65406130; called by muse, mutect2, varscan2
- LRFN5 | c.2027T>G p.L676W | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV53276482; called by muse, mutect2, varscan2
- MAP4K1 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV67711138, COSV67713098; called by muse, mutect2, varscan2
- MAPKBP1 | c.3920G>A p.R1307H (on ENST00000456763 / NM_001128608.2; = p.R1301H on NM_014994.3) | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372334816; called by muse, mutect2
- MARS2 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as COSV56572524; called by muse, mutect2, varscan2
- MATN3 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV68100688; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 13/200 reads (7%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2
- MBOAT7 | c.559A>G p.S187G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV55477740; called by muse, mutect2, varscan2
- MED25 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 167/432 reads (39%) | catalogued as COSV57207612; called by muse, mutect2, varscan2
- MON1B | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV50253800; called by muse, mutect2, varscan2
- NIBAN2 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761011053, COSV64825645; called by muse, varscan2
- NLRC4 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61594942; called by muse, mutect2, varscan2
- NOX5 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52996531; called by muse, mutect2, varscan2
- NPM1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV51583290; called by muse, varscan2
- NTRK2 | c.1447C>G p.H483D (on ENST00000323115 / NM_001369534.1; = p.H499D on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV52878269; called by muse, varscan2
- OPCML | c.708del p.G237Vfs*6 | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | catalogued as COSV100101050, COSV59416556; called by mutect2, pindel, varscan2
- OR11L1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 145/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1252805876, COSV63313810, COSV63315822; called by muse, mutect2, varscan2
- OR4C13 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1555015760; called by muse, mutect2, varscan2
- OR5M11 | c.213G>T p.L71F | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.873); catalogued as COSV73142027; called by muse, varscan2
- PAMR1 | c.1334T>A p.I445N (on ENST00000619888 / NM_001001991.3; = p.I462N on NM_015430.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV53516780; called by muse, mutect2, varscan2
- PASD1 | c.1211T>C p.L404S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV64857958; called by muse, mutect2, varscan2
- PCDH11X | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs750562367, COSV53462647, COSV53483839; called by muse, mutect2, varscan2
- PCDHGA4 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54039094; called by muse, mutect2, varscan2
- PCED1B | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 139/237 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71395213; called by muse, mutect2, varscan2
- PCNX4 | c.1105G>C p.E369Q (on ENST00000406854 / NM_001330177.2; = p.E135Q on NM_022495.5) | Missense Mutation (SNP) | VAF 86/153 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV58303833, COSV58308311; called by muse, mutect2, varscan2
- PDIA5 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV60252771; called by muse, varscan2
- PDILT | c.294T>A p.F98L | Missense Mutation (SNP) | VAF 64/401 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as COSV56705486; called by muse, mutect2, varscan2
- PDZRN4 | c.2492C>G p.S831C (on ENST00000402685 / NM_001164595.2; = p.S573C on NM_013377.4) | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV54218171; called by muse, mutect2, varscan2
- PIEZO2 | c.243G>T p.L81F | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs1217929975, COSV57461489; called by muse, mutect2, varscan2
- PKN1 | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV54404392; called by muse, mutect2, varscan2
- PLAC8L1 | c.517A>T p.K173* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV61014602; called by muse, mutect2, varscan2
- PLCH2 | c.1272T>A p.S424R | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53950141; called by muse, mutect2, varscan2
- PLXNB2 | c.3736C>T p.R1246W | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833930; called by muse, mutect2, varscan2
- POLA1 | c.1626C>A p.F542L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66891001; called by muse, mutect2, varscan2
- PPP1R15B | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.149); catalogued as rs778782356; called by muse, mutect2
- PRDM15 | c.1503C>A p.C501* | Nonsense Mutation (SNP) | VAF 21/204 reads (10%) | catalogued as COSV54158125; called by muse, mutect2
- PRRX1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53411616, COSV53419369; called by muse, mutect2, varscan2
- PSD2 | c.1253C>A p.T418K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51207904, COSV51212681; called by muse, mutect2, varscan2
- PSMD14 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68834063; called by muse, mutect2, varscan2
- PTCHD4 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100261474, COSV59798068; called by muse, mutect2, varscan2
- PTPRC | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV61420471; called by muse, mutect2
- PWWP3B | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV61801848; called by muse, mutect2, varscan2
- PWWP3B | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61801856; called by muse, mutect2, varscan2
- RAB41 | c.432C>A p.N144K (on ENST00000374473 / NM_001363807.1; = p.N143K on NM_001032726.3) | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52105353; called by muse, mutect2, varscan2
- RABGAP1 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 199/494 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs1394801460, COSV58061123; called by muse, mutect2, varscan2
- RB1 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117842; called by muse, mutect2, varscan2
- RBM10 | c.2282G>A p.C761Y | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61312475; called by muse, mutect2, varscan2
- RBM24 | c.649G>A p.A217T (on ENST00000379052 / NM_001143942.2; = p.A172T on NM_153020.2) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs763531759, COSV100552827; called by muse, mutect2, varscan2
- RELB | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs775738995, COSV99672953; called by muse, mutect2
- RHOBTB3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV66103086; called by muse, mutect2, varscan2
- RHOH | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV67807027; called by muse, mutect2, varscan2
- RMI1 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 119/294 reads (40%) | catalogued as rs767370149, COSV57938024; called by muse, mutect2, varscan2
- RNF151 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs560658750, COSV58400473; called by muse, mutect2, varscan2
- RNF165 | c.921G>C p.V307= | Splice Region (SNP) | VAF 43/94 reads (46%) | catalogued as COSV53978143; called by muse, mutect2, varscan2
- RPS6KA6 | c.232G>T p.V78F | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53127286; called by muse, mutect2, varscan2
- RSRP1 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs1392689366; called by muse, mutect2
- SACS | c.802G>T p.G268* | Nonsense Mutation (SNP) | VAF 105/286 reads (37%) | catalogued as COSV66547075; called by muse, mutect2, varscan2
- SAMD9L | c.2230G>T p.G744C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV59085572; called by muse, mutect2, varscan2
- SASH3 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV63556743; called by muse, mutect2, varscan2
- SCN8A | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV61993538; called by muse, mutect2
- SEC16A | c.6718C>A p.P2240T | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV51528400, COSV51541407; called by muse, mutect2, varscan2
- SH3BP4 | c.1964G>A p.S655N | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV60646626; called by muse, mutect2, varscan2
- SLC19A1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.114); catalogued as rs1307518363; called by muse, mutect2, varscan2
- SLC2A13 | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV55128881; called by muse, mutect2, varscan2
- SLC38A5 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58335686; called by muse, mutect2, varscan2
- SLC9C2 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62945712; called by muse, mutect2
- SPHKAP | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 51/178 reads (29%) | catalogued as COSV60895310; called by muse, mutect2, varscan2
- ST18 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52510640; called by muse, mutect2, varscan2
- SUPT16H | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53527267; called by muse, mutect2, varscan2
- TBC1D30 | c.1639G>C p.G547R (on ENST00000542120; = p.G384R on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1358893021; called by muse, varscan2
- TCEAL4 | c.480C>G p.D160E | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV65464149; called by muse, mutect2, varscan2
- TCERG1L | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64047638; called by muse, mutect2, varscan2
- TCF23 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.146); catalogued as COSV56079143; called by muse, mutect2, varscan2
- TDRD9 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59156925; called by muse, varscan2
- THEG | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61075007; called by muse, varscan2
- THOC2 | c.*18G>T | Splice Region (SNP) | VAF 32/104 reads (31%) | catalogued as COSV99834368; called by muse, mutect2
- TNRC18 | c.7781G>A p.G2594D | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1477780668; called by muse, mutect2, varscan2
- TRPC4 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as COSV59001624; called by muse, mutect2, varscan2
- TRPM1 | c.2250G>T p.K750N | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56643042; called by muse, mutect2, varscan2
- TSBP1 | c.1050G>C p.K350N (on ENST00000617061; = p.K355N on NM_006781.5) | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs774401145; called by muse, mutect2, varscan2
- TTN | c.44927A>T p.E14976V (on ENST00000591111; = p.E7552V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | PolyPhen probably damaging (0.943); catalogued as COSV60365765; called by muse, mutect2, varscan2
- TTN | c.44926G>C p.E14976Q (on ENST00000591111; = p.E7552Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | PolyPhen probably damaging (0.961); catalogued as COSV60365795; called by muse, mutect2, varscan2
- UBR3 | c.2985C>G p.H995Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.979); catalogued as COSV55844827; called by muse, mutect2, varscan2
- UNC13C | c.297del p.N100Mfs*9 | Frame Shift Del (DEL) | VAF 39/219 reads (18%) | catalogued as COSV52850550; called by mutect2, pindel, varscan2
- UNC13D | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 31/482 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs748571320; called by muse, mutect2
- URGCP | c.197C>T p.P66L (on ENST00000453200 / NM_001077663.3; = p.P57L on NM_017920.4) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV56253130; called by muse, mutect2
- USP35 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV101489066, COSV71572587, COSV71572988; called by muse, mutect2, varscan2
- USP7 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61217679; called by muse, mutect2, varscan2
- VN1R5 | c.238A>C p.I80L | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs1462896949; called by muse, mutect2, varscan2
- VWA5B2 | c.2444C>A p.P815H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56614433; called by muse, mutect2, varscan2
- XIRP1 | c.3142G>A p.A1048T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV61141589; called by muse, mutect2, varscan2
- ZFP41 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.393); catalogued as COSV58088529; called by muse, mutect2, varscan2
- ZIC4 | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV67173786, COSV67173788; called by muse, mutect2, varscan2
- ZMAT1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65659900; called by muse, mutect2
- ZNF354A | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746729241, COSV59985059; called by muse, mutect2, varscan2
- ZNF536 | c.516C>G p.N172K | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62834736; called by muse, mutect2, varscan2
- ZNF536 | c.3803T>G p.L1268R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62834743; called by muse, mutect2, varscan2
- ZNF804A | c.1229C>G p.T410S | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as rs1283781848, COSV100171043, COSV56466840; called by muse, mutect2
- ZNF99 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1415129406, COSV101233961; called by muse, mutect2, varscan2
- ABHD17A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 65/191 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ACACA | c.1544T>C p.M515T | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY8 | c.2750A>T p.Q917L | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- AHNAK2 | c.4777G>A p.G1593R | Missense Mutation (SNP) | VAF 260/454 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- AKAP4 | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- ANKRD22 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.309); called by muse, mutect2
- ARHGEF40 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- BID | c.142G>T p.D48Y (on ENST00000317361 / NM_197966.2; = p.D2Y on NM_001196.4) | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C19orf18 | c.241A>T p.N81Y | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- CIAO2B | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CRYBG1 | c.4777G>A p.E1593K | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- CSMD1 | c.5451del p.G1818Afs*10 (on ENST00000520002; = p.G1817Afs*10 on NM_033225.6) | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by pindel, varscan2
- DEF6 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DHX29 | c.3712G>A p.D1238N | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); called by mutect2, varscan2
- DIO2 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 150/317 reads (47%) | called by muse, mutect2, varscan2
- DSC2 | c.18del p.S7Pfs*14 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | called by mutect2, pindel, varscan2
- ELN | c.1322C>G p.A441G | Missense Mutation (SNP) | VAF 76/395 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- EPHB1 | c.479C>G p.T160R | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- F5 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM214B | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- FCRL1 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLI1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HEATR5A | c.5018A>T p.K1673M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.132); called by muse, mutect2
- IK | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO7 | c.1695G>A p.M565I | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.265); called by muse, mutect2
- IQSEC3 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2
- IRS4 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP8-1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONRF2 | c.1081T>G p.S361A | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LUM | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAST1 | c.1694del p.G565Afs*77 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- MED8 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGA | c.3134del p.P1045Lfs*17 | Frame Shift Del (DEL) | VAF 44/135 reads (33%) | called by mutect2, pindel, varscan2
- MICAL2 | c.2023A>T p.M675L | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKI67 | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NBEAL1 | c.6236+1G>C p.X2079_splice | Splice Site (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- NCAPH | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- NF2 | c.529dup p.Y177Lfs*26 | Frame Shift Ins (INS) | VAF 29/227 reads (13%) | called by mutect2, pindel, varscan2
- NFKBIB | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUDT8 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- NUP205 | c.2216T>G p.L739R | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR11H12 | c.95T>C p.F32S | Missense Mutation (SNP) | VAF 174/393 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PADI4 | c.1818C>G p.I606M | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PPP1R12B | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- PPP1R2C | c.507C>A p.N169K | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PPP1R9A | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- RHEB | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2
- RIDA | c.11del p.L4* | Frame Shift Del (DEL) | VAF 76/305 reads (25%) | called by mutect2, pindel, varscan2
- RPN2 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 132/505 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC12A6 | c.3346G>A p.E1116K (on ENST00000354181 / NM_001365088.1; = p.E1065K on NM_005135.2) | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- SLC44A2 | c.1458_1461del p.A487Sfs*33 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- SLC6A5 | c.2328del p.L777Wfs*12 | Frame Shift Del (DEL) | VAF 112/407 reads (28%) | called by mutect2, pindel, varscan2
- SPRR2D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 252/445 reads (57%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- STAT5B | c.704_706del p.K235del | In Frame Del (DEL) | VAF 41/302 reads (14%) | called by pindel, varscan2
- SYT9 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 74/424 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TFE3 | c.1455G>C p.Q485H | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- THOC2 | c.*16A>T | Splice Region (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2
- TOMM20 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 37/256 reads (14%) | called by muse, mutect2, varscan2
- TRIM3 | c.1631A>C p.N544T | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TSPAN17 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTC6 | c.112G>A p.E38K (on ENST00000267368; = p.E1307K on NM_001310135.3) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, varscan2
- USP19 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR4 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XRN1 | c.1528C>G p.P510A | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF234 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 10/305 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); called by muse, mutect2
- ACLY | c.6G>T p.S2= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV61253122; called by muse, mutect2, varscan2
- AHR | c.621G>A p.Q207= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as COSV54126593; called by muse, mutect2, varscan2
- AL358113.1 | c.3303G>A p.Q1101= | Silent (SNP) | VAF 36/506 reads (7%) | called by muse, mutect2
- BEST2 | c.1032C>T p.R344= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as rs776535761, COSV50362182; called by muse, mutect2, varscan2
- BICRA | c.3135G>C p.L1045= | Silent (SNP) | VAF 59/147 reads (40%) | called by muse, varscan2
- C1QL2 | c.834G>A p.T278= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV55606204; called by muse, mutect2, varscan2
- CACNA1E | c.6687C>G p.S2229= (on ENST00000367573 / NM_001205293.3; = p.S2186= on NM_000721.4) | Silent (SNP) | VAF 95/164 reads (58%) | catalogued as COSV62427307; called by muse, mutect2, varscan2
- CALCB | c.36C>G p.L12= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV60834360; called by muse, mutect2, varscan2
- CCDC97 | c.84G>C p.L28= | Silent (SNP) | VAF 77/221 reads (35%) | called by muse, mutect2
- CORO2B | c.1140C>G p.T380= | Silent (SNP) | VAF 63/254 reads (25%) | catalogued as rs1393368789, COSV55957883; called by muse, mutect2, varscan2
- DIO1 | c.168C>T p.F56= | Silent (SNP) | VAF 89/280 reads (32%) | catalogued as rs746714497, COSV50776500; called by muse, mutect2, varscan2
- DOCK2 | c.543C>A p.I181= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV56989787; called by muse, mutect2, varscan2
- F9 | c.315C>G p.G105= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as COSV54382454, COSV54382530; called by muse, mutect2, varscan2
- FAT4 | c.11745C>T p.A3915= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs920683746, COSV58710180; called by muse, mutect2
- FOXRED1 | c.414C>T p.I138= | Silent (SNP) | VAF 84/376 reads (22%) | called by muse, mutect2, varscan2
- GAREM2 | c.1047C>A p.R349= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV68226248; called by muse, mutect2, varscan2
- GATA1 | c.336C>A p.T112= | Silent (SNP) | VAF 47/204 reads (23%) | catalogued as COSV64961843; called by muse, mutect2, varscan2
- GJA3 | c.654C>T p.N218= | Silent (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- GNPTG | c.201C>T p.L67= | Silent (SNP) | VAF 43/350 reads (12%) | catalogued as rs1318071298, COSV50189947; called by muse, mutect2, varscan2
- HBG2 | c.225C>G p.A75= | Silent (SNP) | VAF 170/590 reads (29%) | catalogued as COSV57964620; called by muse, mutect2, varscan2
- HEPH | c.2145C>G p.V715= (on ENST00000343002; = p.V448= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/266 reads (21%) | catalogued as COSV57972897; called by muse, mutect2, varscan2
- HMG20A | c.249A>G p.K83= | Silent (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- HS3ST6 | c.951C>G p.V317= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV53536937; called by muse, mutect2
- IGHG1 | c.666C>A p.A222= | Silent (SNP) | VAF 94/201 reads (47%) | called by muse, mutect2, varscan2
- IGKV1D-42 | c.129C>T p.I43= | Silent (SNP) | VAF 77/184 reads (42%) | catalogued as rs1472279116; called by muse, mutect2, varscan2
- IGSF3 | c.2262C>G p.L754= (on ENST00000369486 / NM_001007237.3; = p.L774= on NM_001542.4) | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs768787385; called by muse, mutect2, varscan2
- KDM3B | c.1740G>A p.K580= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1275402657, COSV58695708; called by muse, mutect2, varscan2
- KIAA1549L | c.4185G>A p.L1395= (on ENST00000321505; = p.L1692= on NM_012194.3) | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as rs779478008; called by muse, mutect2, varscan2
- LILRA6 | c.993G>A p.P331= | Silent (SNP) | VAF 50/308 reads (16%) | catalogued as rs759762653, COSV54440729; called by muse, mutect2, varscan2
- LIMD1 | c.1104G>A p.L368= | Silent (SNP) | VAF 55/161 reads (34%) | catalogued as COSV56270593; called by muse, mutect2, varscan2
- LRP2 | c.9495G>A p.Q3165= | Silent (SNP) | VAF 59/180 reads (33%) | catalogued as COSV55575930; called by muse, mutect2, varscan2
- MAP4K4 | c.540G>A p.R180= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as COSV56341085; called by muse, mutect2, varscan2
- MCM4 | c.1827G>T p.A609= | Silent (SNP) | VAF 66/286 reads (23%) | catalogued as COSV50626136; called by muse, mutect2, varscan2
- MITF | c.1434G>C p.L478= (on ENST00000448226 / NM_006722.3; = p.L378= on NM_000248.4) | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV58836144; called by muse, mutect2, varscan2
- MYOM3 | c.369C>T p.R123= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV58401385; called by muse, mutect2, varscan2
- NME8 | c.168G>A p.L56= | Silent (SNP) | VAF 22/398 reads (6%) | catalogued as COSV99554014; called by muse, mutect2
- NUTM1 | c.270C>A p.V90= | Silent (SNP) | VAF 58/176 reads (33%) | catalogued as COSV61548588; called by muse, mutect2, varscan2
- OR2T27 | c.390G>T p.L130= | Silent (SNP) | VAF 41/290 reads (14%) | called by mutect2, varscan2
- OR51M1 | c.555C>A p.V185= | Silent (SNP) | VAF 60/214 reads (28%) | catalogued as COSV60784257, COSV60785544; called by muse, mutect2, varscan2
- PALB2 | c.1821C>T p.L607= | Silent (SNP) | VAF 82/295 reads (28%) | catalogued as rs1555460634, COSV55170688; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAX5 | c.132T>C p.L44= | Silent (SNP) | VAF 86/470 reads (18%) | called by muse, varscan2
- PCNT | c.7659G>C p.G2553= | Silent (SNP) | VAF 84/203 reads (41%) | catalogued as COSV64033330; called by muse, mutect2, varscan2
- PDE6B | c.423C>T p.H141= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs148575945; called by muse, mutect2, varscan2
- PDGFD | c.151C>A p.R51= | Silent (SNP) | VAF 30/176 reads (17%) | catalogued as COSV100161481, COSV56369436; called by muse, varscan2
- PLRG1 | c.1200C>T p.F400= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs867615378, COSV57424783; called by muse, mutect2, varscan2
- PPP1R12B | c.1029G>A p.E343= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- PTPRC | c.960T>C p.T320= | Silent (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- REST | c.1431A>G p.K477= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as rs765344572, COSV58363132; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF151 | c.360G>C p.S120= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as COSV58400005; called by muse, mutect2, varscan2
- SLCO3A1 | c.1257G>T p.G419= | Silent (SNP) | VAF 66/195 reads (34%) | catalogued as COSV59237937; called by muse, mutect2, varscan2
- SLITRK3 | c.1591C>A p.R531= | Silent (SNP) | VAF 76/385 reads (20%) | catalogued as rs964642608, COSV53848848, COSV53850739, COSV53853797; called by muse, mutect2, varscan2
- SLITRK3 | c.1590C>A p.A530= | Silent (SNP) | VAF 76/383 reads (20%) | catalogued as COSV53845287, COSV53854126; called by muse, mutect2, varscan2
- SPEF2 | c.2343C>T p.V781= | Silent (SNP) | VAF 40/305 reads (13%) | called by muse, mutect2, varscan2
- TRPS1 | c.3360C>G p.S1120= (on ENST00000220888 / NM_001330599.2; = p.S1133= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as COSV55257733; called by muse, mutect2, varscan2
- URB1 | c.4053C>T p.T1351= | Silent (SNP) | VAF 82/182 reads (45%) | catalogued as rs767233071, COSV66962195; called by muse, mutect2, varscan2
- VAV1 | c.2319C>T p.I773= | Silent (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- VCAN | c.906C>T p.A302= | Silent (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- VWA5B2 | c.2445C>A p.P815= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV56614447; called by muse, mutect2, varscan2
- ZNF469 | c.5169G>A p.K1723= (on ENST00000437464; = p.K1751= on NM_001367624.2) | Silent (SNP) | VAF 196/503 reads (39%) | catalogued as COSV71259437; called by muse, mutect2, varscan2
- ZNF507 | c.345T>G p.L115= | Silent (SNP) | VAF 77/171 reads (45%) | called by muse, mutect2, varscan2
- ZNF618 | c.150G>A p.L50= | Silent (SNP) | VAF 50/323 reads (15%) | catalogued as COSV55930274; called by muse, mutect2, varscan2
- AC008060.1 | n.258G>C | RNA (SNP) | VAF 24/652 reads (4%) | called by muse, mutect2
- AC090155.1 | n.127C>G | RNA (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2
- ADAM12 | c.2113+868C>T | Intron (SNP) | VAF 59/162 reads (36%) | catalogued as rs769084306; called by muse, mutect2, varscan2
- ADORA2A | c.-274-1671C>T | Intron (SNP) | VAF 49/163 reads (30%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+827G>A | Intron (SNP) | VAF 52/194 reads (27%) | catalogued as COSV61450600; called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39150C>G | Intron (SNP) | VAF 57/273 reads (21%) | called by muse, mutect2, varscan2
- C22orf34 | n.149A>T | RNA (SNP) | VAF 15/193 reads (8%) | called by muse, mutect2
- CFAP410 | c.642+223C>G | Intron (SNP) | VAF 10/156 reads (6%) | catalogued as rs921549893; called by muse, mutect2
- CICP23 | chr11:130703 G>C | 3'Flank (SNP) | VAF 53/457 reads (12%) | called by muse, mutect2, varscan2
- CYB5RL | chr1:54171209 G>T | 3'Flank (SNP) | VAF 59/373 reads (16%) | called by muse, mutect2, varscan2
- CYYR1 | c.334+2178C>T | Intron (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- CYYR1 | c.-199G>T | 5'UTR (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+2020C>G | Intron (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- DMTF1 | c.1049+260C>T | Intron (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- DST | c.4297-1739C>T | Intron (SNP) | VAF 244/600 reads (41%) | catalogued as COSV55041140; called by muse, mutect2, varscan2
- FASLG | c.-13C>T | 5'UTR (SNP) | VAF 51/551 reads (9%) | called by muse, mutect2
- FEZ1 | c.-46+724C>A | Intron (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- FEZ1 | c.-200C>T | 5'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- FKBP6 | c.265+48G>A | Intron (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2
- GHRL | c.-766+71T>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- INKA1 | c.-48G>T | 5'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1590C>T | Intron (SNP) | VAF 18/93 reads (19%) | catalogued as rs913287885, COSV56229536; called by muse, mutect2, varscan2
- KIAA1586 | c.-26G>T | 5'UTR (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- KMT2C | c.2533-17C>G | Intron (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- LGI2 | c.*3556G>C | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- LINC02649 | n.46G>A | RNA (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- MAML3 | c.2079+65G>A | Intron (SNP) | VAF 62/387 reads (16%) | catalogued as COSV59071877; called by muse, mutect2, varscan2
- MAP7D3 | chrX:136256307 G>T | 5'Flank (SNP) | VAF 21/118 reads (18%) | catalogued as COSV60171530, COSV60172698; called by muse, mutect2, varscan2
- MIR6511B2 | chr16:15130679 G>A | 3'Flank (SNP) | VAF 64/229 reads (28%) | called by muse, mutect2, varscan2
- NF1 | c.7739-12A>T | Intron (SNP) | VAF 73/265 reads (28%) | called by muse, mutect2, varscan2
- NIT2 | c.7+237C>T | Intron (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- NKAIN4 | c.532+15T>A | Intron (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- NPY6R | n.718C>A | RNA (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- OR2M1P | n.207G>A | RNA (SNP) | VAF 14/149 reads (9%) | catalogued as rs765465696; called by muse, mutect2
- PPP1R12B | c.2863-5434G>T | Intron (SNP) | VAF 52/124 reads (42%) | catalogued as COSV51790166; called by muse, mutect2, varscan2
- PTAR1 | c.982+20G>C | Intron (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2
- SDHD | c.315-1691G>T | Intron (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- SEMA4A | c.568+41C>T | Intron (SNP) | VAF 58/324 reads (18%) | called by muse, mutect2, varscan2
- SH3BGRL | c.-59G>T | 5'UTR (SNP) | VAF 51/203 reads (25%) | called by muse, mutect2, varscan2
- SHISAL1 | c.-11C>T | 5'UTR (SNP) | VAF 20/80 reads (25%) | catalogued as rs773678103; called by muse, mutect2, varscan2
- SLC26A8 | chr6:36024806 G>T | 5'Flank (SNP) | VAF 106/307 reads (35%) | called by muse, mutect2, varscan2
- SLIT2 | c.179+1077C>T | Intron (SNP) | VAF 51/204 reads (25%) | catalogued as rs1325062951; called by muse, mutect2, varscan2
- SP4 | c.-40C>T | 5'UTR (SNP) | VAF 10/92 reads (11%) | catalogued as rs1239356052; called by muse, mutect2, varscan2
- SPEF2 | c.4448-2735T>C | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SPG7 | c.1642+908G>T | Intron (SNP) | VAF 61/159 reads (38%) | called by muse, mutect2, varscan2
- SSPOP | n.2711G>T | RNA (SNP) | VAF 19/52 reads (37%) | catalogued as COSV50489433; called by muse, mutect2, varscan2
- TRAV26-1 | c.-16C>T | 5'UTR (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- TRDN | c.794-1353C>A | Intron (SNP) | VAF 102/204 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.10360+3457G>A | Intron (SNP) | VAF 15/80 reads (19%) | catalogued as rs1183407718, COSV60365836; called by muse, mutect2, varscan2
- UMODL1 | c.1900-102A>G | Intron (SNP) | VAF 35/345 reads (10%) | catalogued as COSV61161554; called by muse, mutect2, varscan2
- UMPS | c.*3014C>G | 3'UTR (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
